Gene-level copy-number profile of tumor specimen C3L-08144-01 from CPTAC case C3L-08144, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 72.0 years (26,311 days).
Specimen C3L-08144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7264bbf7-d729-4fdd-88aa-4ca2ed1d9953.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08144-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,765 have no estimate.
https://portal.gdc.cancer.gov/files/e25a2de3-413a-4c5d-8d24-04e467407d86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 658; copy number 2: 22,002; copy number 3: 16,586; copy number 4: 10,220; copy number 5: 5,997; copy number 6: 1,422; copy number 7: 334; copy number 8: 822; copy number 9: 92; copy number 10: 95; copy number 11: 2; copy number 12: 1; copy number 13: 5; copy number 15: 2; copy number 17: 4; copy number 26: 10; copy number 54: 1; copy number 81: 3; copy number 90: 30; copy number 97: 38.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:35,724,759–35,725,142, 1 gene: MRPL50P1.
- chr4:44,704,405–44,704,965, 1 gene (within-gene range 0–1): AC096586.1.
- chr4:70,334,981–70,337,116, 1 gene: CABS1.
- chr4:186,328,716–186,329,601, 1 gene (within-gene range 0–1): SLC25A5P6.
- chr7:74,773,962–74,789,376, 1 gene: NCF1.
- chr8:85,744,543–85,828,467, 7 genes: REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P.
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–2): AL513422.1.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr11:89,854,953–89,862,893, 1 gene: TRIM51BP.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:20,729,747–20,775,998, 5 genes: AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,858 genes in 169 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–1,780,457, 77 genes, copy number 5–8 (broad region; genes not listed).
- chr1:6,264,269–11,674,354, 147 genes, copy number 5–9 (broad region; genes not listed).
- chr1:14,692,129–16,073,651, 51 genes, copy number 5–6: TBCAP2, AL031293.1, TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC, CELA2A, CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C.
- chr1:16,197,854–17,439,677, 60 genes, copy number 7: ARHGEF19-AS1, ARHGEF19, ANO7L1, CPLANE2, MT1XP1, FBXO42, SZRD1, RPL22P3, SPATA21, NECAP2, LINC01772, CROCCP3, RNU1-1, AL137802.2, AL137802.3, AL137802.1, LINC01783, RNU1-6P, AL355149.1, NBPF1, AL137798.1, CROCCP2, AL137798.3, MST1P2, AL137798.2, RNU1-3, AL021920.2, EIF1AXP1, ESPNP, AL021920.1, AL021920.3, CROCC, CROCCP4, RNU1-4, MST1L, BX284668.1, BX284668.3, MIR3675, BX284668.2, RNU1-5P, BX284668.5, BX284668.4, RNU1-2, BX284668.6, MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3, SDHB, PADI2, LINC02783, AL590644.2, PADI1, PADI3, MIR3972, PADI4, PADI6, RCC2-AS1, RCC2.
- chr1:22,633,258–24,143,140, 55 genes, copy number 5–7: MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, HNRNPR, ZNF436, ZNF436-AS1, Y_RNA, AL109936.2, TCEA3, AL357134.1, ASAP3, E2F2, AL021154.1, ID3, AL450043.1, MDS2, AL451000.1, RPL11, ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1, IL22RA1.
- chr1:143,419,625–156,299,307, 589 genes, copy number 5 (broad region; genes not listed).
- chr1:159,834,474–248,937,043, 1,805 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:104,063,039–112,362,812, 95 genes, copy number 5–11 (broad region; genes not listed).
- chr3:160,016,024–161,503,942, 30 genes, copy number 5–6: LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr3:169,003,022–170,085,392, 28 genes, copy number 5–6: LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3.
- chr3:170,222,424–173,336,965, 52 genes, copy number 5–7: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, KLF7P1, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:178,164,008–179,789,401, 30 genes, copy number 5–6: AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13.
- chr3:182,921,240–187,180,908, 127 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–43,707,405, 663 genes, copy number 8–97 (broad region; genes not listed).
- chr6:43,671,202–49,713,590, 90 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr6:49,823,712–58,438,364, 131 genes, copy number 5–7 (broad region; genes not listed).
- chr7:19,719,315–26,213,607, 101 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr9:66,721,158–68,540,883, 38 genes, copy number 5–6 (within-gene range 5–8): ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3, CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1, BX664730.1, Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252.
- chr10:3,009,976–7,118,469, 91 genes, copy number 5–7 (broad region; genes not listed).
- chr10:12,349,547–16,005,923, 69 genes, copy number 5–8 (broad region; genes not listed).
- chr10:16,207,821–19,790,401, 41 genes, copy number 5–7 (within-gene range 3–7): RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1, MALRD1, UBE2V2P1.
- chr10:20,095,125–25,176,276, 78 genes, copy number 5–6 (within-gene range 4–9) (broad region; genes not listed).
- chr10:25,924,448–27,542,239, 37 genes, copy number 5–6 (within-gene range 5–7): AL358612.1, MYO3A, GAD2, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18.
- chr10:29,409,402–31,031,937, 32 genes, copy number 5–7 (within-gene range 4–7): SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P, AL353093.1, JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, LYZL2, SVIL2P, LINC02644, ZNF438.
- chr10:31,602,862–36,626,138, 76 genes, copy number 5–7 (broad region; genes not listed).
- chr10:37,523,011–42,552,822, 50 genes, copy number 6: TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP.
- chr10:133,070,929–133,778,699, 53 genes, copy number 5–8: ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr11:59,456,938–60,184,666, 34 genes, copy number 5–7: OR4D6, OR4D10, OR4D8P, OR4D11, OR4D9, OR4D7P, LINC02739, AP000442.1, OSBP, MIR3162, PATL1, AP000640.2, RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A.
- chr13:29,509,414–53,801,489, 440 genes, copy number 5–8 (within-gene range 5–9) (broad region; genes not listed).
- chr14:18,333,726–20,560,931, 126 genes, copy number 5–6 (broad region; genes not listed).
- chr14:20,870,278–21,159,060, 27 genes, copy number 5: AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1, RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P, OR5AU1.
- chr16:14,435,700–19,268,332, 142 genes, copy number 5–10 (broad region; genes not listed).
- chr17:15,627,960–16,492,193, 46 genes, copy number 5–9: TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:39,461,486–40,093,867, 30 genes, copy number 90 (within-gene range 3–90): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA.
- chr17:42,124,978–49,939,819, 401 genes, copy number 5 (broad region; genes not listed).
- chr18:20,946,906–22,647,688, 42 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.
- chr19:29,811,991–58,605,223, 1,624 genes, copy number 5–10 (broad region; genes not listed).
- chr20:30,278,906–32,439,319, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:48,921,711–64,327,972, 363 genes, copy number 6–8 (within-gene range 6–9) (broad region; genes not listed).
- chr21:8,680,538–13,120,807, 47 genes, copy number 8–15: CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
